Gene-level copy-number profile of tumor specimen TCGA-AR-A24K-01A from TCGA case TCGA-AR-A24K, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.4 years (16,961 days).
Specimen TCGA-AR-A24K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.51797bbf-7ed7-49ef-b23f-d3ba37a31ae6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75752c94-4ad1-4d2e-852c-9e05c3cddfdc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 33; copy number 2: 8,612; copy number 3: 19,405; copy number 4: 25,912; copy number 5: 1,073; copy number 6: 1,163; copy number 7: 3,380; copy number 8: 168; copy number 9: 57; copy number 10: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24K-01A-11D-A166-01): tumor purity 0.78, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 71 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:80,265,528–81,924,348, 52 genes, copy number 9: AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235.
- chr8:82,098,451–82,160,577, 1 gene, copy number 9: LINC02839.
- chr8:87,540,835–87,755,718, 1 gene, copy number 10 (within-gene range 7–10): AF121898.1.
- chr8:87,598,462–89,415,071, 13 genes, copy number 10: IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4.
- chr11:8,106,056–8,594,289, 4 genes, copy number 9 (within-gene range 4–9): RIC3, RIC3-DT, LMO1, STK33.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
